Somatic mutation profile of tumor specimen TARGET-30-PATHUU-01A (aliquot TARGET-30-PATHUU-01A-01D) from TARGET case TARGET-30-PATHUU, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 1.9 years (705 days).
Specimen TARGET-30-PATHUU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a08605f2-ee50-4b25-939f-93aed3197a37.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATHUU-10A (Blood Derived Normal), aliquot TARGET-30-PATHUU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0c4ed6b-3504-48d4-9857-749c76a2694e

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1966A>G p.K656E (on ENST00000447712 / NM_023110.3; = p.K654E on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869320694, COSV58327161, COSV58340654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
